ALCHEMIST case ALCH-ADRX — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/c57317b9-9e93-4e2e-b56c-725fc76548f5

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenosquamous carcinoma: Age at diagnosis: 73.9 years (26,976 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ADRX-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ADRX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ADRX-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 52; Percent normal cells: 18; Percent necrosis: 4; Percent stromal cells: 38; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
